Somatic mutation profile of tumor specimen 0DU1XB from CCDI case PBCKGW, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 4.9 years (1,806 days).
Specimen 0DU1XB: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3e9f7142-a677-4ce1-afca-ee80b5551eb5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DU1W9 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/11dd0dbd-e4de-4654-b0d1-e5bd764efe43

The open-access MAF lists 14 somatic variants for this specimen: 11 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 2, Nonsense Mutation 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.97T>C p.S33P | Missense Mutation (SNP) | VAF 245/567 reads (43%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1057519886, COSV62688086, COSV62689225, COSV62704131; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.388C>G p.R130G | Missense Mutation (SNP) | VAF 228/562 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121909224, CM094223, CM971273, COSV64288384, COSV64288463, COSV64297940, COSV64311187; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CEP350 | c.1966C>T p.R656* | Nonsense Mutation (SNP) | VAF 287/706 reads (41%) | catalogued as rs1463093879; called by muse, mutect2, varscan2
- KRT33B | c.1177C>T p.R393C | Missense Mutation (SNP) | VAF 18/756 reads (2%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs202226873, COSV52442056; called by muse, mutect2
- NSD2 | c.3295G>A p.E1099K | Missense Mutation (SNP) | VAF 138/357 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs772470710, COSV56386422; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TOGARAM2 | c.2945C>G p.T982R | Missense Mutation (SNP) | VAF 133/300 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.237); catalogued as COSV65422215; called by muse, mutect2, varscan2
- VPS4B | c.754C>T p.R252C | Missense Mutation (SNP) | VAF 164/366 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs372889875; called by muse, mutect2, varscan2
- ANKRD13B | c.1735G>A p.G579S | Missense Mutation (SNP) | VAF 370/848 reads (44%) | SIFT tolerated (0.91); PolyPhen benign (0.001); called by muse, mutect2
- DENND5A | c.32C>T p.A11V | Missense Mutation (SNP) | VAF 17/524 reads (3%) | SIFT tolerated (0.28); PolyPhen benign (0.048); called by muse, mutect2
- MUC5B | c.1475T>C p.I492T | Missense Mutation (SNP) | VAF 17/570 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2
- PLCH2 | c.2227G>C p.V743L | Missense Mutation (SNP) | VAF 189/363 reads (52%) | SIFT tolerated (0.13); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- FCGBP | c.3192G>A p.E1064= | Silent (SNP) | VAF 18/572 reads (3%) | called by muse, mutect2
- P2RX6 | c.972C>T p.L324= | Silent (SNP) | VAF 32/667 reads (5%) | catalogued as rs573348820; called by muse, mutect2
- MRPS31 | c.-21G>C | 5'UTR (SNP) | VAF 247/602 reads (41%) | catalogued as rs756915511, COSV100062320; called by muse, mutect2, varscan2
